Gene-level copy-number profile of tumor specimen AP-NMZS-LL from APOLLO case AP-NMZS, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lepidic adenocarcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-NMZS-LL: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a59d57d-7939-4ff4-b92f-2a21b25ea5b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-NMZS-XS (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/cd535400-fc9c-448f-b94f-87d50035e456

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 708; copy number 1: 8,409; copy number 2: 42,881; copy number 3: 6,402.

Homozygous deletions (total copy number 0; autosomes only): 708 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,963,314–75,913,242, 18 genes: AC133865.1, AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4.
- chr1:110,936,369–111,041,925, 6 genes: AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54.
- chr6:58,386,799–58,386,961, 1 gene: AL603755.1.
- chr6:61,240,898–61,241,311, 1 gene: AL356131.1.
- chr7:56,805,336–57,139,864, 10 genes: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1, ZNF479.
- chr7:62,275,361–63,843,505, 44 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1, AC079355.1, CICP24, AC079355.2, AC092634.5.
- chr8:43,542,076–46,793,064, 10 genes: AC134698.2, AC139365.2, AC139365.1, AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15.
- chr9:21,695,176–25,089,151, 34 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:38,403,189–38,452,153, 1 gene (within-gene range 0–1): AL133216.2.
- chr10:38,452,987–38,466,176, 2 genes: CICP9, AL133216.1.
- chr10:42,149,310–42,281,819, 5 genes: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr10:45,302,298–45,315,608, 1 gene: OR13A1.
- chr11:48,880,111–48,951,895, 5 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP.
- chr12:37,575,587–38,087,392, 3 genes: ZNF970P, AK6P2, CLUHP8.
- chr19:52,259,076–58,605,223, 496 genes (broad region; genes not listed).
- chr21:13,095,305–15,067,837, 59 genes: ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5.
- chr21:17,210,469–17,296,596, 2 genes: NEK4P1, AP000457.1.
- chr21:17,705,408–18,485,879, 9 genes (within-gene range 0–1): AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
